Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6533, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6533-01A (Primary Tumor).

Examination: Histopathological examination

Examination No.: [REDACTED]

Material: Multiple organ resection – transverse colon with the distal part of the stomach

Material collected on: [REDACTED] Material received on: [REDACTED]

Expected time of examination: [REDACTED]

Clinical diagnosis: Cancer of the transverse colon infiltrating the stomach

Examination performed on [REDACTED]

Macroscopic description:

30 cm length of the large intestine, with perintestinal fat tissue sized 30 x 8 x 2cm, the omentum sized 30 x 15 cm and part of the stomach sized 11 x 8 x 4 cm. Cauliflower-shaped tumour sized 10 x 8 x 4 cm found in the intestinal mucosa. The lesion surrounds 100% of the intestine circumference, 10 cm from the proximal cut line and 10 cm from the distal cut line. The lesion invaded macroscopically through the stomach wall.

Microscopic description:

Adenocarcinoma tubulopapillare (G1). Infiltratio carcinomatosa parietis intestini crassi totius et parietis ventriculi. Minimum side margin is 0 cm. Incision lines ends free of neoplastic lesions.

Sinus histiocytosis lymphonodorum (No VIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli; Tubulopapillar adenocarcinoma of the colon. (G1; Dukes B; Astler-Coller B3; pT4b; pN0).

Compliance validated [REDACTED]

CALL YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file c73e9714-b13a-4bc5-b0de-665e704c9079 (TCGA-D5-6533.638BCBB3-047B-4CD5-9674-BC0401B6E3EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).